Somatic mutation profile of tumor specimen TCGA-EE-A2GC-06A (aliquot TCGA-EE-A2GC-06A-11D-A197-08) from TCGA case TCGA-EE-A2GC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 85.1 years (31,092 days).
Specimen TCGA-EE-A2GC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 595eb6d3-d6f8-4264-afd9-6b80b1dc07c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GC-10A (Blood Derived Normal), aliquot TCGA-EE-A2GC-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8fe555d-03d6-4a79-8389-d515c66e8c2b

The open-access MAF lists 2,808 somatic variants for this specimen: 1,824 protein-altering or splice-affecting, 911 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,658, Silent 911, Nonsense Mutation 106, Intron 26, RNA 23, Splice Region 22, Splice Site 18, 3'UTR 12, Frame Shift Del 11, 5'Flank 5, 5'UTR 4, Translation Start Site 4.

Variants (750 of 2,808; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL6 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs867576130, COSV51651017; called by muse, mutect2, varscan2
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 150/282 reads (53%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, varscan2
- CRAT | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.146); catalogued as rs762425351, COSV58875953; ClinVar: likely pathogenic; called by mutect2, varscan2
- CYBB | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 25/32 reads (78%) | catalogued as rs137854588, CM910097, COSV66086104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs763801533, CM1414365, COSV58628166; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 47/132 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, mutect2, varscan2
- ERBB4 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs535202189, COSV53533661; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GALC | c.621+1G>A p.X207_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as rs759511006, COSV54330328; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs796052549, CM138250, COSV58045061; ClinVar: likely pathogenic; called by muse, varscan2
- HSPB1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894020, CM056337, COSV50349761; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6715C>T p.Q2239* (on ENST00000358273 / NM_001042492.3; = p.Q2218* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 41/87 reads (47%) | catalogued as rs1131691093, CD1415208, COSV62194886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP63 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen possibly damaging (0.664); catalogued as rs147148566, COSV53202265, COSV53220854; called by muse, mutect2, varscan2
- A2M | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778604418, COSV59383298; called by muse, mutect2, varscan2
- A2ML1 | c.3398A>G p.N1133S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.079); catalogued as rs763783506, COSV55285945, COSV55298506; called by muse, mutect2, varscan2
- ABCA12 | c.2526G>A p.W842* (on ENST00000272895 / NM_173076.3; = p.W524* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 35/61 reads (57%) | catalogued as COSV55975497; called by muse, mutect2, varscan2
- ABCA12 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55975512; called by muse, mutect2, varscan2
- ABCA13 | c.13201G>A p.G4401S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.253); catalogued as rs763237392, COSV68948268, COSV68950670; called by muse, varscan2
- ABCA4 | c.6110C>T p.A2037V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100933260; called by muse, varscan2
- ABCA8 | c.3794C>T p.A1265V | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV52212182; called by muse, mutect2, varscan2
- ABCB1 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs28381914; called by muse, mutect2, varscan2
- ABCB4 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55941718; called by muse, mutect2, varscan2
- ABCB5 | c.1759C>T p.R587* (on ENST00000404938 / NM_001163941.2; = p.R142* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as rs746177833, COSV51704222, COSV51720176; called by muse, mutect2, varscan2
- ABCC1 | c.4024C>T p.R1342W | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201020041; called by muse, mutect2, varscan2
- ABCC12 | c.3049T>C p.Y1017H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs942253370, COSV60918226; called by muse, mutect2, varscan2
- ABCC4 | c.2333T>C p.F778S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV65318273; called by muse, mutect2, varscan2
- ABCC4 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV65313409; called by muse, mutect2, varscan2
- ABCC6 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229678; called by muse, mutect2, varscan2
- ABHD17A | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs775151143, COSV51751971; called by muse, varscan2
- ABT1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51290995, COSV99223353; called by muse, mutect2, varscan2
- AC090517.4 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV50998630; called by muse, mutect2, varscan2
- ACAP3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.219); catalogued as COSV61223586; called by muse, mutect2, varscan2
- ACKR1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV63674596; called by muse, mutect2, varscan2
- ACMSD | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51609694; called by muse, mutect2, varscan2
- ACRBP | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57525376; called by muse, mutect2, varscan2
- ACSL6 | c.1331G>A p.G444E (on ENST00000379240; = p.G469E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57305018; called by muse, mutect2, varscan2
- ACSM2B | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | catalogued as rs765182724, COSV61656914; called by muse, mutect2, varscan2
- ACSM4 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68069400; called by muse, mutect2, varscan2
- ACSM5 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1475409516, COSV59374894; called by muse, mutect2
- ACSM6 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV58980733; called by muse, mutect2, varscan2
- ACSS3 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs752461783, COSV54101283; called by muse, mutect2, varscan2
- ACTN1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV51988567, COSV51997587; called by muse, mutect2, varscan2
- ACTR1A | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100883728; called by muse, mutect2, varscan2
- ACTRT2 | c.548A>C p.H183P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV65760515; called by muse, mutect2, varscan2
- ADAM18 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55855120; called by muse, mutect2, varscan2
- ADAM19 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1404393732, COSV57439133; called by muse, mutect2, varscan2
- ADAM28 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867843641, COSV56098311; called by muse, mutect2, varscan2
- ADAM28 | c.1568-1G>A p.X523_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56105430; called by muse, mutect2, varscan2
- ADAMTS18 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV51417659, COSV51419530; called by muse, mutect2, varscan2
- ADAMTS18 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs1054279062, COSV51410456; called by muse, mutect2, varscan2
- ADAMTS2 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV52393324; called by muse, varscan2
- ADAMTS20 | c.5639C>T p.S1880L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67136798; called by muse, mutect2, varscan2
- ADAMTS20 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867354506, COSV67132676; called by muse, mutect2
- ADAMTS6 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV58683162; called by muse, varscan2
- ADAMTSL2 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV63206247; called by muse, mutect2, varscan2
- ADCY1 | c.3037G>A p.G1013R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52042450; called by muse, mutect2, varscan2
- ADCY10 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV63242870; called by muse, mutect2, varscan2
- ADCY6 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57170534; called by muse, mutect2, varscan2
- ADD2 | c.849G>A p.K283= | Splice Region (SNP) | VAF 39/87 reads (45%) | catalogued as COSV52471209; called by muse, mutect2, varscan2
- ADGRB1 | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.995); catalogued as rs372124996; called by muse, mutect2, varscan2
- ADGRE1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV51680995; called by muse, mutect2, varscan2
- ADGRF5 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.735); catalogued as COSV51930822; called by muse, mutect2, varscan2
- ADGRV1 | c.10249G>A p.G3417S | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.401); catalogued as COSV67995388; called by muse, mutect2, varscan2
- ADGRV1 | c.12109G>A p.E4037K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV67994866; called by muse, mutect2
- ADH1B | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs768162102, COSV59295799; called by muse, mutect2, varscan2
- ADK | c.133C>T p.L45F (on ENST00000286621; = p.L28F on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99693524; called by muse, mutect2, varscan2
- ADK | c.134T>G p.L45R (on ENST00000286621; = p.L28R on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99693526; called by muse, mutect2, varscan2
- ADPRM | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV101126107; called by muse, mutect2, varscan2
- ADPRM | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101126109; called by muse, mutect2, varscan2
- AFM | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs866976795, COSV56922168; called by muse, mutect2, varscan2
- AGO4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751046556, COSV64616822; called by muse, varscan2
- AHCYL2 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.909); catalogued as COSV61491197; called by muse, mutect2, varscan2
- AHDC1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV55942351; called by muse, mutect2, varscan2
- AIFM2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.122); catalogued as COSV57160946; called by muse, mutect2, varscan2
- AK7 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50882388; called by muse, mutect2, varscan2
- AKAP9 | c.7510C>T p.Q2504* (on ENST00000359028; = p.Q2480* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV62350517; called by muse, mutect2, varscan2
- AKR1C3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV65911218; called by muse, mutect2, varscan2
- ALAD | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV52960857; called by muse, mutect2, varscan2
- ALDH1B1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs772685418, COSV66620633; called by muse, mutect2, varscan2
- ALDH1L2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV51559789; called by muse, mutect2, varscan2
- ALMS1 | c.9799C>T p.P3267S | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52521951; called by muse, varscan2
- ALMS1 | c.10591C>T p.P3531S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as COSV52521960; called by muse, mutect2, varscan2
- ALOX15 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs370447055; called by muse, mutect2, varscan2
- ALPI | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.915); catalogued as COSV55016175; called by muse, mutect2, varscan2
- ALPK2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64497167; called by muse, mutect2, varscan2
- ALPL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs138587317, CM1512156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429719993, COSV51892548; called by muse, mutect2, varscan2
- AMPD1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587779370, COSV62417012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMTN | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV59489696, COSV59490202; called by muse, mutect2, varscan2
- AMY1C | c.879-1G>A p.X293_splice | Splice Site (SNP) | VAF 52/574 reads (9%) | catalogued as COSV100915241; called by muse, varscan2
- ANGPT1 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865919805; called by muse, varscan2
- ANK3 | c.7003G>A p.E2335K | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs769392075, COSV55047176; called by muse, mutect2, varscan2
- ANK3 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780139; called by muse, varscan2
- ANK3 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866520390, COSV99782479; called by muse, varscan2
- ANKDD1A | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 136/358 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV63089186; called by muse, mutect2, varscan2
- ANKMY1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56040885; called by muse, mutect2, varscan2
- ANKRD30A | c.1572G>A p.K524= (on ENST00000611781; = p.K468= on NM_052997.2) | Splice Region (SNP) | VAF 26/63 reads (41%) | catalogued as COSV64621218; called by muse, mutect2, varscan2
- ANKRD30A | c.1787G>A p.G596E (on ENST00000611781; = p.G540E on NM_052997.2) | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as COSV64616394; called by muse, mutect2
- ANKRD35 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV62911401; called by muse, mutect2, varscan2
- ANKRD35 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782512174, COSV62911601; called by muse, mutect2, varscan2
- ANKRD35 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV62909387, COSV62912068; called by muse, mutect2
- ANKRD50 | c.4243G>A p.E1415K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV72384975, COSV72386320; called by muse, mutect2, varscan2
- ANKS1B | c.2620C>T p.P874S (on ENST00000547776 / NM_152788.4; = p.P100S on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60375407; called by muse, mutect2, varscan2
- ANKS6 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs768090267, COSV62052205; called by muse, mutect2, varscan2
- ANO1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs751658523, COSV100304503; called by muse, mutect2, varscan2
- ANO2 | c.1790G>A p.G597D (on ENST00000356134 / NM_001278597.3; = p.G601D on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV59043220; called by muse, mutect2, varscan2
- ANO2 | c.1610C>T p.S537F (on ENST00000356134 / NM_001278597.3; = p.S541F on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV59043238; called by muse, mutect2, varscan2
- ANO5 | c.440T>G p.L147W | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61090246; called by muse, mutect2, varscan2
- ANPEP | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.23); catalogued as rs774559825, COSV55589577; called by muse, varscan2
- APPL2 | c.511C>G p.R171G | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV51593771; called by muse, mutect2, varscan2
- ARAP2 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV58292130; called by muse, mutect2
- ARFGAP1 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs751451578, COSV62264024; called by muse, mutect2, varscan2
- ARHGAP19 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV57396061; called by muse, varscan2
- ARHGAP20 | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV52819252; called by muse, mutect2, varscan2
- ARHGAP31 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51798945; called by muse, mutect2, varscan2
- ARHGEF11 | c.4121C>T p.T1374I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.479); catalogued as rs774027159, COSV59358658; called by muse, mutect2, varscan2
- ARHGEF19 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as COSV54618665; called by muse, mutect2, varscan2
- ARHGEF26 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62851883; called by muse, mutect2, varscan2
- ARHGEF40 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs935991117, COSV53884330; called by muse, mutect2, varscan2
- ARID3A | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1460900570, COSV99708546; called by muse, mutect2, varscan2
- ARMC4 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.139); catalogued as COSV59456466, COSV59461306; called by muse, mutect2, varscan2
- ARMC4 | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV59473774; called by muse, varscan2
- ARMC4 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.348); catalogued as rs200299616, COSV59473820; called by muse, varscan2
- ARMC4 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV59465239; called by muse, varscan2
- ARNTL | c.1699T>C p.S567P (on ENST00000403290 / NM_001297719.2; = p.S566P on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.949); catalogued as COSV53401659; called by muse, mutect2, varscan2
- ARPP21 | c.1905+2T>C p.X635_splice | Splice Site (SNP) | VAF 23/85 reads (27%) | catalogued as COSV51808158; called by muse, mutect2, varscan2
- ARPP21 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV51808172; called by muse, mutect2, varscan2
- ASAH2 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 183/422 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100270166; called by muse, mutect2, varscan2
- ASB17 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.314); catalogued as COSV52412098; called by muse, mutect2, varscan2
- ASCC3 | c.3796C>T p.Q1266* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV61233757; called by muse, mutect2, varscan2
- ASNSD1 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99641388; called by muse, mutect2, varscan2
- ASPM | c.5492T>A p.I1831N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54138596; called by muse, mutect2, varscan2
- ASPM | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54138613; called by muse, mutect2, varscan2
- ATAD3A | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749571503, COSV59235869; called by muse, mutect2, varscan2
- ATL2 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184363, COSV60056491; called by muse, mutect2, varscan2
- ATP12A | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770576902, COSV54516836; called by muse, mutect2, varscan2
- ATP13A1 | c.2204A>G p.E735G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV52291207; called by muse, mutect2, varscan2
- ATP13A2 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV58703720; called by muse, mutect2, varscan2
- ATP13A4 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61320511; called by muse, mutect2, varscan2
- ATP13A4 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV61327162; called by muse, mutect2, varscan2
- ATP13A4 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV55075274; called by muse, mutect2, varscan2
- ATP2B1 | c.3265G>A p.D1089N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV53812768; called by muse, mutect2, varscan2
- ATP2C2 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52301323; called by muse, mutect2, varscan2
- ATP6V1C2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV55364498; called by muse, mutect2, varscan2
- ATP6V1H | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV62220379; called by muse, mutect2, varscan2
- ATP7B | c.1710C>T p.I570= | Splice Region (SNP) | VAF 15/63 reads (24%) | catalogued as COSV54439226; called by muse, mutect2, varscan2
- ATP8B1 | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52180230; called by muse, mutect2, varscan2
- ATP8B3 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59541046; called by muse, mutect2, varscan2
- ATP9B | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56961345; called by muse, mutect2, varscan2
- ATRN | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV53534384; called by muse, mutect2, varscan2
- ATRN | c.3523C>T p.R1175C | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53526182; called by muse, mutect2, varscan2
- ATXN2L | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.932); catalogued as rs1467681661, COSV57378741; called by muse, mutect2, varscan2
- ATXN2L | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV57378793; called by muse, mutect2, varscan2
- AXDND1 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs146570827, COSV100858688; called by mutect2, varscan2
- AXIN1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99250339; called by muse, mutect2, varscan2
- AXIN1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99250342; called by muse, mutect2, varscan2
- B4GALNT2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs776879040, COSV55928297; called by muse, mutect2, varscan2
- BACE2 | c.312+1G>A p.X104_splice | Splice Site (SNP) | VAF 7/12 reads (58%) | catalogued as COSV57743710; called by muse, mutect2, varscan2
- BANK1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59845318, COSV59849860; called by muse, mutect2, varscan2
- BARHL1 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV55037135; called by muse, mutect2, varscan2
- BCAR3 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772245403, COSV53079394; called by muse, mutect2, varscan2
- BCAT1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs377761696; called by muse, mutect2
- BCL7C | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs776443654, COSV53064506; called by muse, mutect2, varscan2
- BCLAF1 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.947); catalogued as rs146790565, COSV62143933; called by muse, mutect2, varscan2
- BIN2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57208017; called by muse, mutect2, varscan2
- BIRC6 | c.3871C>T p.R1291W | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs763922153, COSV70198081; called by muse, mutect2, varscan2
- BLID | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as COSV73340402; called by muse, mutect2, varscan2
- BLM | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 166/477 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV61927384; called by muse, mutect2, varscan2
- BLNK | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1165286551, COSV56414934; called by muse, mutect2, varscan2
- BPIFA1 | c.429-1G>A p.X143_splice | Splice Site (SNP) | VAF 91/266 reads (34%) | catalogued as rs775518516, COSV62825045, COSV62825217; called by muse, mutect2, varscan2
- BPIFB4 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64952347; called by muse, mutect2, varscan2
- BRCA2 | c.7585G>A p.G2529S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs398122585, COSV101204664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.7586G>A p.G2529D | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV101204665; called by muse, mutect2, varscan2
- BRDT | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62865123; called by muse, varscan2
- BRF2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV55103364; called by muse, mutect2, varscan2
- BRINP2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64180248; called by muse, mutect2, varscan2
- BRS3 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65711308; called by muse, mutect2, varscan2
- BRWD1 | c.3559G>A p.G1187S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV60902746; called by muse, mutect2, varscan2
- BSDC1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs1220845674, COSV61982352; called by muse, mutect2, varscan2
- BTBD7 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54135955; called by muse, mutect2, varscan2
- BTN3A2 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs1377536413, COSV100709722, COSV62688289; called by muse, mutect2, varscan2
- BUD13 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 255/413 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52770519; called by muse, mutect2, varscan2
- BZW2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV51757661; called by muse, mutect2, varscan2
- C10orf120 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV61492630; called by muse, mutect2, varscan2
- C11orf53 | c.749T>A p.V250E | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV54722626; called by muse, mutect2, varscan2
- C12orf40 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV61137777; called by muse, varscan2
- C12orf40 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as rs1018177244, COSV61130151, COSV61137563; called by muse, varscan2
- C12orf50 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs757520062, COSV53898848; called by muse, mutect2, varscan2
- C12orf50 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV53893420; called by muse, varscan2
- C15orf39 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62298227; called by muse, mutect2
- C17orf97 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV64077467; called by muse, varscan2
- C1QC | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65890084; called by muse, mutect2, varscan2
- C1QTNF2 | c.979C>T p.P327S (on ENST00000393975; = p.P282S on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV67433326; called by muse, mutect2, varscan2
- C1RL | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56925776; called by muse, varscan2
- C1orf116 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100847965, COSV63944593; called by muse, mutect2, varscan2
- C21orf58 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1202867829, COSV99388190; called by muse, mutect2, varscan2
- C2orf73 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58312064; called by muse, mutect2
- C2orf78 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as COSV68519409; called by muse, mutect2, varscan2
- C3orf22 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV59073321; called by muse, mutect2, varscan2
- C6 | c.1991T>G p.V664G | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54718532, COSV99667483; called by muse, mutect2, varscan2
- C7 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496551, COSV57471678, COSV57472471; called by muse, mutect2, varscan2
- C7 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV57471178; called by muse, mutect2, varscan2
- C8A | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1007715803, COSV63485387; called by muse, mutect2, varscan2
- C8B | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs780551849, COSV64779655; called by muse, mutect2, varscan2
- C8orf34 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57413002; called by muse, mutect2, varscan2
- CABS1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV56734538; called by muse, varscan2
- CABS1 | c.425A>C p.E142A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV56733363, COSV56734548; called by muse, varscan2
- CACNA1A | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as COSV64189509; called by muse, mutect2, varscan2
- CACNA1C | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs866162457, COSV59708199; called by muse, mutect2, varscan2
- CACNA1E | c.6022C>T p.P2008S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.343); catalogued as COSV62424027; called by muse, mutect2, varscan2
- CACNA1E | c.6563G>A p.G2188E (on ENST00000367573 / NM_001205293.3; = p.G2145E on NM_000721.4) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62389127, COSV62424046; called by muse, varscan2
- CACNA1G | c.5756C>T p.S1919F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV61739451; called by mutect2, varscan2
- CACNA1S | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV62943633; called by muse, mutect2, varscan2
- CACNA1S | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62939749; called by muse, mutect2, varscan2
- CACNB2 | c.1937G>A p.R646Q (on ENST00000324631 / NM_201596.3; = p.R591Q on NM_000724.4) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.974); catalogued as rs374454040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG2 | c.297G>A p.R99= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55638231, COSV55638841; called by mutect2, varscan2
- CACNG2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1487422848, COSV55637032; called by muse, mutect2, varscan2
- CADPS | c.2393G>A p.R798K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99341062; called by muse, mutect2, varscan2
- CALCR | c.673G>A p.G225R (on ENST00000649521 / NM_001164737.2; = p.G209R on NM_001742.4) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV64011889; called by muse, mutect2, varscan2
- CALD1 | c.1537C>T p.P513S (on ENST00000361675 / NM_033138.4; = p.P258S on NM_004342.7) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62654014; called by muse, mutect2, varscan2
- CAPN10 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as COSV54379776; called by muse, mutect2, varscan2
- CAPRIN1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs766532737, COSV58222356; called by muse, mutect2, varscan2
- CAPRIN2 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 122/364 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV51835497; called by muse, mutect2, varscan2
- CAPSL | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs1367715056, COSV68438728, COSV68439408; called by muse, mutect2, varscan2
- CAPZA3 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs868010711, COSV56850834; called by muse, mutect2, varscan2
- CARD11 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV67796694; called by muse, mutect2, varscan2
- CARMIL3 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100549791, COSV57728336; called by muse, mutect2, varscan2
- CARS1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV53460997; called by muse, mutect2, varscan2
- CASP2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775475286, COSV60083554; called by muse, mutect2, varscan2
- CASP7 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61883361; called by muse, varscan2
- CASQ2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.419); catalogued as COSV54773988; called by muse, mutect2, varscan2
- CAST | c.878C>T p.A293V (on ENST00000341926; = p.A376V on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57789473; called by muse, mutect2, varscan2
- CASZ1 | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV59737859; called by muse, mutect2, varscan2
- CASZ1 | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as rs755775776, COSV59740977; called by muse, mutect2, varscan2
- CAT | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573480; called by muse, mutect2, varscan2
- CATSPERD | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV67537364; called by muse, mutect2, varscan2
- CAVIN2 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58425891; called by muse, mutect2, varscan2
- CBLB | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV51436740, COSV99914474; called by muse, mutect2, varscan2
- CBY2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV60117578; called by muse, mutect2, varscan2
- CCDC141 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55374109; called by muse, mutect2, varscan2
- CCDC178 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.215); catalogued as COSV55763501; called by muse, mutect2, varscan2
- CCDC54 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53758113, COSV53759291; called by muse, mutect2, varscan2
- CCDC60 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs1367882802, COSV59550470; called by muse, mutect2, varscan2
- CCKAR | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs762474661, COSV55160620, COSV55163977; called by muse, mutect2, varscan2
- CCNB3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52079627; called by muse, mutect2, varscan2
- CCND2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54225976; called by muse, mutect2, varscan2
- CCP110 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV66818170; called by muse, mutect2, varscan2
- CCR5 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52753057; called by muse, mutect2, varscan2
- CCT8L2 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63463808; called by muse, mutect2, varscan2
- CD163L1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58021843; called by muse, mutect2, varscan2
- CD44 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53536915; called by muse, mutect2, varscan2
- CD93 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs867528103, COSV55663356, COSV55666402; called by muse, mutect2, varscan2
- CDC40 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs556916492, COSV57012269; called by muse, mutect2, varscan2
- CDCP2 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61285876; called by muse, mutect2, varscan2
- CDCP2 | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313705; called by muse, mutect2, varscan2
- CDH12 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs374444907; called by muse, mutect2, varscan2
- CDH12 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66447672; called by muse, mutect2, varscan2
- CDH12 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV66447674; called by muse, mutect2, varscan2
- CDH16 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV55339715; called by muse, mutect2, varscan2
- CDH23 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1564706920, COSV54952627; called by muse, mutect2, varscan2
- CDH26 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV54854885; called by muse, mutect2, varscan2
- CDH4 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs759647875, COSV64644118; called by muse, mutect2, varscan2
- CDH6 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54076848, COSV99035111; called by muse, mutect2, varscan2
- CDH8 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54846434; called by muse, mutect2, varscan2
- CDH9 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as rs778294609, COSV50320746, COSV50455190; called by muse, mutect2, varscan2
- CDK11A | c.395C>T p.A132V (on ENST00000378633 / NM_001313896.2; = p.A142V on NM_024011.4) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1164971376, COSV62266874; called by muse, varscan2
- CDK12 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs143648695, COSV71002912; called by muse, mutect2, varscan2
- CDK3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV56913840, COSV56916072; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62577772; called by muse, varscan2
- CDKAL1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 88/474 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs866091749, COSV51191899; called by muse, mutect2, varscan2
- CDKAL1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 160/435 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs767890331, COSV51191947; called by muse, mutect2, varscan2
- CDKL1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 43/104 reads (41%) | catalogued as COSV53582703; called by muse, mutect2, varscan2
- CDKL3 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54744943; called by muse, mutect2, varscan2
- CDO1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV51666395; called by muse, mutect2, varscan2
- CDT1 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV56350153; called by muse, mutect2, varscan2
- CDYL2 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV73653894, COSV73654974; called by muse, mutect2, varscan2
- CEACAM6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52267617; called by muse, mutect2, varscan2
- CECR2 | c.3470C>T p.P1157L (on ENST00000342247 / NM_001290047.2; = p.P973L on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV52848156; called by muse, mutect2, varscan2
- CELSR2 | c.2642G>A p.R881Q | Missense Mutation (SNP) | VAF 252/404 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1425992292, COSV54779320; called by muse, mutect2, varscan2
- CELSR2 | c.3959-1G>A p.X1320_splice | Splice Site (SNP) | VAF 107/164 reads (65%) | catalogued as COSV54779328; called by muse, mutect2, varscan2
- CELSR3 | c.9698G>A p.G3233D | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1293906862, COSV51150767; called by muse, mutect2, varscan2
- CENPE | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs772375325, COSV54390198, COSV99478375, COSV99479049; called by muse, mutect2, varscan2
- CEP250 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV61174425; called by muse, mutect2
- CEP250 | c.5002C>T p.Q1668* | Nonsense Mutation (SNP) | VAF 82/210 reads (39%) | catalogued as COSV61174430; called by muse, mutect2, varscan2
- CFAP206 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51536141; called by muse, mutect2, varscan2
- CFAP46 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.97); catalogued as COSV63954776; called by muse, mutect2, varscan2
- CFAP54 | c.7867G>A p.E2623K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.421); catalogued as COSV61575213; called by muse, mutect2, varscan2
- CFAP58 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV63836407; called by muse, mutect2, varscan2
- CFAP58 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779819795, COSV63834698, COSV63835270; called by muse, mutect2, varscan2
- CFAP58 | c.2610G>A p.M870I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV63836411; called by muse, mutect2, varscan2
- CFAP65 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.571); catalogued as COSV55390329; called by muse, mutect2, varscan2
- CFAP91 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599558, COSV56340073; called by muse, mutect2, varscan2
- CFH | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV62778825; called by muse, mutect2, varscan2
- CFH | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100810236, COSV66405849; called by muse, varscan2
- CFHR3 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs1156859095, COSV66401929; called by muse, mutect2, varscan2
- CFI | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67099953; called by muse, mutect2, varscan2
- CFTR | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV50047277, COSV50086381; called by muse, mutect2, varscan2
- CHAF1A | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56676369; called by muse, mutect2, varscan2
- CHAT | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV60326044; called by muse, mutect2, varscan2
- CHD6 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58554754; called by muse, mutect2, varscan2
- CHDH | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59460065; called by muse, mutect2, varscan2
- CHRM2 | c.428T>G p.M143R | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57784615; called by muse, mutect2, varscan2
- CHRNA2 | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV53559793; called by muse, mutect2, varscan2
- CHRNA6 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV52381056; called by muse, mutect2, varscan2
- CHRNB4 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55718385; called by muse, mutect2, varscan2
- CHST6 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs201069424, COSV60001717; called by muse, mutect2, varscan2
- CIITA | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV60854212, COSV60862071; called by muse, mutect2, varscan2
- CILK1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1174096796; called by muse, mutect2
- CLCN1 | c.2142T>G p.D714E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV58374447; called by mutect2, varscan2
- CLCN6 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV56743057; called by muse, mutect2, varscan2
- CLCNKB | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs368764495, COSV100989727; called by muse, mutect2, varscan2
- CLEC3B | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1299330131, COSV56110517; called by muse, mutect2
- CLEC4D | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs946297864, COSV55230883; called by muse, mutect2, varscan2
- CLEC5A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396699; called by muse, mutect2, varscan2
- CLGN | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276241084, COSV57776521; called by muse, mutect2, varscan2
- CLPTM1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 77/477 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV61613090; called by muse, mutect2, varscan2
- CLSTN3 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs141776530; called by muse, mutect2, varscan2
- CMKLR1 | c.933G>A p.M311I (on ENST00000312143 / NM_001142344.2; = p.M309I on NM_004072.3) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1387396471, COSV56441932; called by muse, mutect2, varscan2
- CMYA5 | c.9140C>T p.P3047L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV71409472; called by muse, mutect2, varscan2
- CNGA3 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV55628219; called by muse, mutect2, varscan2
- CNOT6 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs1474022647, COSV56164060; called by muse, mutect2, varscan2
- CNOT6L | c.1166C>T p.A389V (on ENST00000504123 / NM_001286790.2; = p.A384V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.145); catalogued as COSV99362236; called by muse, mutect2, varscan2
- CNST | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV63622463; called by muse, mutect2, varscan2
- COG7 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56153177; called by muse, mutect2, varscan2
- COL11A1 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62186969, COSV62197325; called by muse, mutect2
- COL11A2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.979); catalogued as rs1234849793, COSV59502434; called by muse, mutect2, varscan2
- COL12A1 | c.6931C>T p.P2311S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1396549511, COSV59407804; called by muse, mutect2, varscan2
- COL13A1 | c.1156G>A p.E386K (on ENST00000398978 / NM_001130103.2; = p.E329K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV62573770; called by muse, mutect2, varscan2
- COL17A1 | c.3812G>A p.G1271E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62229385; called by muse, mutect2
- COL3A1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV58596449; called by muse, mutect2, varscan2
- COL4A1 | c.2814G>A p.M938I | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV65421952; called by muse, mutect2, varscan2
- COL4A2 | c.2188T>C p.F730L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs775703612, COSV64634122; called by muse, mutect2
- COL4A2 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV64624427; called by muse, mutect2, varscan2
- COL4A4 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs745926070, COSV61636633; called by muse, mutect2, varscan2
- COL4A4 | c.3643C>T p.P1215S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs765071781, COSV61636638; called by muse, varscan2
- COL4A4 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV61636650; called by muse, mutect2, varscan2
- COL4A4 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095034, COSV61636654; called by muse, mutect2, varscan2
- COL4A4 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61636658; called by muse, mutect2, varscan2
- COL5A1 | c.4982G>A p.G1661E | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65665766; called by muse, mutect2, varscan2
- COL6A3 | c.6788G>A p.R2263Q | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs779508804, COSV55082724, COSV55109613; called by muse, mutect2, varscan2
- COL6A3 | c.2530G>A p.G844S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1254158878, COSV55089367, COSV55109631; called by muse, mutect2, varscan2
- COL9A1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100294343; called by muse, mutect2
- CPA3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.124); catalogued as COSV56047385, COSV99936103; called by muse, mutect2, varscan2
- CPA6 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745811365, COSV52721197, COSV52740263; called by muse, mutect2, varscan2
- CPA6 | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99913995; called by muse, mutect2, varscan2
- CPE | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs867760910, COSV68579839; called by muse, mutect2, varscan2
- CPE | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 133/415 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.381); catalogued as rs774780895, COSV68582594; called by muse, mutect2, varscan2
- CPM | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as rs760786418, COSV58036051; called by muse, mutect2, varscan2
- CPNE4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV70196930, COSV70197493; called by muse, mutect2, varscan2
- CPNE6 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV53746486; called by muse, mutect2, varscan2
- CPS1 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51824246, COSV51829084; called by muse, mutect2, varscan2
- CR1L | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV54331471; called by muse, mutect2, varscan2
- CRACD | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV51731395; called by muse, mutect2, varscan2
- CRB2 | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV63505575; called by muse, mutect2, varscan2
- CREB3L1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV55830552; called by muse, mutect2, varscan2
- CREBBP | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52140713; called by muse, mutect2, varscan2
- CRTC3 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51600457; called by muse, mutect2, varscan2
- CSF1R | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs759253407, COSV53843142; called by muse, mutect2, varscan2
- CSF2RA | c.71A>T p.K24I | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.55); catalogued as COSV62626793; called by muse, mutect2, varscan2
- CSMD1 | c.8752C>T p.P2918S (on ENST00000520002; = p.P2917S on NM_033225.6) | Missense Mutation (SNP) | VAF 116/323 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.158); catalogued as COSV59349442; called by muse, mutect2, varscan2
- CSMD1 | c.7880C>T p.S2627F (on ENST00000520002; = p.S2626F on NM_033225.6) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs267601891, COSV59284813; called by muse, mutect2, varscan2
- CSMD1 | c.7508G>A p.G2503E (on ENST00000520002; = p.G2502E on NM_033225.6) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV59310410; called by muse, mutect2, varscan2
- CSMD1 | c.4882G>A p.G1628S (on ENST00000520002; = p.G1627S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV59382608; called by muse, mutect2, varscan2
- CSMD2 | c.7016G>A p.G2339E | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV53914554; called by muse, mutect2, varscan2
- CSMD2 | c.5636C>T p.S1879F | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53962655; called by muse, mutect2, varscan2
- CSMD2 | c.4330C>A p.P1444T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV53962675; called by muse, mutect2, varscan2
- CSMD3 | c.7162C>T p.H2388Y (on ENST00000297405 / NM_001363185.1; = p.H2284Y on NM_052900.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV52264776, COSV52291109; called by muse, mutect2, varscan2
- CSMD3 | c.1477G>A p.E493K (on ENST00000297405 / NM_001363185.1; = p.E389K on NM_052900.3) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52318007; called by muse, mutect2, varscan2
- CSNK1G2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs934160560, COSV55339797; called by muse, mutect2, varscan2
- CSTF1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV99410359; called by muse, mutect2, varscan2
- CTAGE1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs776939884, COSV66944864; called by muse, mutect2, varscan2
- CTNNA2 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58146271, COSV58155739, COSV58180531; called by muse, mutect2
- CTNNA3 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375721994; called by muse, mutect2, varscan2
- CTNND2 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV58927714; called by muse, mutect2, varscan2
- CTR9 | c.45+1G>T p.X15_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as COSV63729657; called by muse, mutect2, varscan2
- CTU2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368079417, COSV56344722; called by muse, mutect2
- CUBN | c.10351G>A p.D3451N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs145661638; ClinVar: uncertain significance; called by mutect2, varscan2
- CUBN | c.5402G>A p.G1801E | Missense Mutation (SNP) | VAF 124/254 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV64727181; called by muse, mutect2, varscan2
- CXCL5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV56018371; called by muse, mutect2, varscan2
- CYLC1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV61415859; called by muse, mutect2, varscan2
- CYLC2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV66339598; called by muse, mutect2, varscan2
- CYP11B1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as COSV52828773, COSV99455740; called by muse, mutect2, varscan2
- CYP11B1 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs375224541, COSV52826623; called by muse, mutect2, varscan2
- CYP1A2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59661056; called by muse, mutect2, varscan2
- CYP27C1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775249425, COSV100080060, COSV58866594; called by muse, mutect2, varscan2
- CYP27C1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1230226469, COSV100080063; called by muse, mutect2, varscan2
- CYP2A7 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV52506528; called by muse, mutect2, varscan2
- CYP2C18 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142667327, COSV53674528; called by muse, mutect2, varscan2
- CYP4F12 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.207); catalogued as rs1263415539, COSV61175126; called by muse, mutect2, varscan2
- CYP4Z1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV61966706; called by muse, mutect2, varscan2
- CYP8B1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV60225854, COSV60227577; called by muse, mutect2, varscan2
- DACH2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64185747; called by muse, mutect2, varscan2
- DAO | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57322080; called by muse, varscan2
- DCC | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.147); catalogued as COSV59115235, COSV59135259; called by muse, mutect2, varscan2
- DCC | c.2423T>A p.L808H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59135292, COSV59135816; called by muse, mutect2, varscan2
- DCC | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1568102148, COSV59135309; called by muse, mutect2, varscan2
- DCD | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV53201171; called by muse, mutect2, varscan2
- DCHS1 | c.4805C>T p.S1602F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV55042710; called by muse, mutect2, varscan2
- DCLK3 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV69364725; called by muse, mutect2, varscan2
- DCTN1 | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62620155; called by muse, mutect2, varscan2
- DDX3X | c.850G>A p.E284K (on ENST00000399959; = p.E285K on NM_001356.5) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864532; called by muse, mutect2, varscan2
- DDX60 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs776523299, COSV67096775; called by muse, mutect2, varscan2
- DDX60 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV101190674, COSV67099333; called by muse, mutect2, varscan2
- DEFA6 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as COSV52405919; called by muse, mutect2, varscan2
- DENND1A | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as rs779697484, COSV65356456; called by muse, mutect2, varscan2
- DEPTOR | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs147092773; called by muse, mutect2, varscan2
- DGKI | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55975347, COSV99935955; called by muse, mutect2
- DIAPH1 | c.3791C>T p.A1264V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99342438; called by muse, mutect2, varscan2
- DIDO1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV56614074; called by muse, mutect2, varscan2
- DIO3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs766968940, COSV63774611; called by muse, mutect2, varscan2
- DIRAS2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV101005916; called by muse, mutect2, varscan2
- DKK2 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV53403524, COSV99567989; called by muse, varscan2
- DKK3 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1445466834, COSV58870519; called by muse, mutect2, varscan2
- DLEC1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57306637; called by muse, mutect2, varscan2
- DLGAP2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV70101224; called by muse, mutect2, varscan2
- DLK1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs191731751, COSV57990804; called by muse, mutect2, varscan2
- DLL3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770966935, COSV52693963; called by muse, mutect2, varscan2
- DMBT1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as rs866531447, COSV57562080; called by muse, mutect2, varscan2
- DMBT1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759038747, COSV57534000; called by muse, mutect2, varscan2
- DMBT1 | c.7252C>T p.L2418F (on ENST00000338354 / NM_001377530.1; = p.L1661F on NM_004406.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.311); catalogued as COSV57562154; called by muse, mutect2, varscan2
- DMTN | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56114595; called by muse, mutect2, varscan2
- DNAAF1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV57578967; called by muse, mutect2, varscan2
- DNAAF5 | c.2401C>G p.P801A | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs995200421, COSV52421366; called by muse, mutect2, varscan2
- DNAH11 | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60981117; called by muse, mutect2, varscan2
- DNAH11 | c.8015C>T p.A2672V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1339423010, COSV60981134; called by muse, mutect2, varscan2
- DNAH11 | c.9922G>A p.E3308K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV60981149; called by muse, mutect2, varscan2
- DNAH11 | c.10167G>A p.K3389= | Splice Region (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60981165; called by muse, mutect2, varscan2
- DNAH11 | c.12128A>G p.K4043R | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60981182; called by muse, mutect2, varscan2
- DNAH3 | c.10529G>A p.G3510E | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0.151); catalogued as COSV99769371; called by muse, mutect2, varscan2
- DNAH3 | c.10528G>A p.G3510R | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.093); catalogued as COSV54558942; called by muse, mutect2, varscan2
- DNAH3 | c.222G>A p.Q74= | Splice Region (SNP) | VAF 15/63 reads (24%) | catalogued as COSV54551427; called by muse, mutect2, varscan2
- DNAH5 | c.12153G>A p.M4051I | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs1376118646, COSV54251991; called by muse, mutect2, varscan2
- DNAH5 | c.8050G>A p.G2684R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54245402; called by muse, mutect2, varscan2
- DNAH5 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV54219615; called by muse, mutect2, varscan2
- DNAH7 | c.11299G>A p.E3767K | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs770923070, COSV56786210; called by muse, mutect2, varscan2
- DNAH7 | c.5620C>T p.R1874* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs267599141, COSV56755304; called by muse, mutect2, varscan2
- DNAH8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 57/158 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs750965126, COSV59480326; called by muse, mutect2, varscan2
- DNAH8 | c.1495C>T p.H499Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59480343, COSV59481995; called by muse, mutect2, varscan2
- DNAH8 | c.3664G>A p.V1222I | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as COSV59480362; called by muse, mutect2, varscan2
- DNAH8 | c.7186G>A p.E2396K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV59480380; called by muse, mutect2, varscan2
- DNAH9 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs756428546, COSV52335454; called by muse, mutect2, varscan2
- DNAI2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs368225621, COSV56758767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB7 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV53423851; called by muse, mutect2, varscan2
- DNAJC17 | c.384C>T p.I128= | Splice Region (SNP) | VAF 14/36 reads (39%) | catalogued as rs146094788; called by muse, mutect2, varscan2
- DNAJC30 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV56095627; called by muse, mutect2, varscan2
- DNAJC5B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV52536452; called by muse, mutect2, varscan2
- DNAJC5G | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs756654028, COSV56081250; called by muse, mutect2, varscan2
- DNM3 | c.2334G>C p.R778S (on ENST00000355305 / NM_001350206.2; = p.R772S on NM_015569.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.055); catalogued as COSV62464151, COSV62467211; called by muse, mutect2, varscan2
- DOC2A | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58752711; called by muse, mutect2, varscan2
- DOCK1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1271767610, COSV54759985; called by muse, mutect2, varscan2
- DOCK6 | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs1371924386, COSV53922420; called by muse, mutect2, varscan2
- DPEP1 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV55361906; called by muse, mutect2, varscan2
- DPH7 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778299640, COSV53021781, COSV99483330; called by muse, mutect2, varscan2
- DPP10 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59683381, COSV59727528; called by muse, mutect2
- DPP6 | c.1999T>C p.F667L (on ENST00000377770 / NM_001364500.2; = p.F605L on NM_001936.5) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.389); catalogued as COSV59645051; called by muse, mutect2, varscan2
- DPYD | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64591966; called by muse, mutect2, varscan2
- DPYS | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs751371011, COSV60913626; called by muse, mutect2, varscan2
- DPYS | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60913632; called by muse, mutect2, varscan2
- DSC1 | c.2425G>A p.G809R | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.955); catalogued as rs1358204708, COSV57151550; called by muse, mutect2, varscan2
- DSCAM | c.5455G>A p.E1819K | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV68030907; called by muse, mutect2, varscan2
- DSEL | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59494751; called by muse, mutect2, varscan2
- DSG1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57134255; called by muse, mutect2, varscan2
- DSG1 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV57134582, COSV57135087; called by muse, mutect2, varscan2
- DSG2 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as rs770270723, COSV55202928; called by muse, mutect2, varscan2
- DSG3 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57129673; called by muse, mutect2, varscan2
- DSG3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV57124458, COSV57125106; called by muse, mutect2, varscan2
- DSG3 | c.2358G>A p.M786I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs767532668, COSV57128646; called by muse, mutect2, varscan2
- DSP | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65796004; called by muse, mutect2
- DST | c.3559C>T p.L1187F (on ENST00000361203 / NM_001374722.1; = p.L861F on NM_001723.6) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55039717; called by muse, mutect2, varscan2
- DTNA | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.842); catalogued as rs1275678831, COSV52022477; called by muse, mutect2
- DUS1L | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs766051331, COSV57648557; called by muse, mutect2, varscan2
- DUSP29 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV58301640; called by muse, mutect2, varscan2
- DUXA | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs772135803, COSV73729702; called by muse, mutect2, varscan2
- DYNC1H1 | c.8128G>T p.G2710W | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64142438; called by muse, mutect2, varscan2
- DYNC1I1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV61463225; called by muse, mutect2, varscan2
- DYSF | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766529008, COSV99250577; called by muse, mutect2, varscan2
- E2F7 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747334392, COSV59743518; called by muse, mutect2, varscan2
- EBF2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs934603583, COSV68780580; called by muse, mutect2, varscan2
- EFCAB6 | c.3454G>A p.G1152S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53072530; called by mutect2, varscan2
- EFCAB6 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV53072540; called by muse, mutect2, varscan2
- EFCAB6 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs906091427, COSV53070476; called by muse, mutect2, varscan2
- EFEMP2 | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV57261512; called by muse, mutect2, varscan2
- EHMT1 | c.3206C>G p.S1069C | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71778695; called by muse, mutect2, varscan2
- ELF2 | c.1780T>G p.*594Eext*17 (on ENST00000379550 / NM_001331036.2; = p.*534Eext*17 on NM_006874.4) | Nonstop Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV55495908; called by muse, mutect2, varscan2
- ELMO1 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV60324702; called by muse, mutect2, varscan2
- EMB | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772964478, COSV100296593, COSV57484510; called by muse, mutect2, varscan2
- EMB | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as COSV57484521; called by muse, mutect2, varscan2
- EMP1 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV56999368; called by muse, mutect2, varscan2
- ENPP1 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 46/135 reads (34%) | catalogued as COSV62936256, COSV62936957; called by muse, mutect2, varscan2
- ENPP6 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57072211; called by muse, varscan2
- ENTPD1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868220888, COSV64604339; called by muse, mutect2, varscan2
- EPHA1 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99314785; called by muse, mutect2, varscan2
- EPHB3 | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV57806105; called by muse, mutect2, varscan2
- EPS15L1 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs865983780, COSV50170185; called by muse, mutect2, varscan2
- EPX | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs747916329, COSV56599246; called by muse, mutect2, varscan2
- EPYC | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1174204335, COSV53802144; called by muse, mutect2, varscan2
- ERBB4 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as COSV61522574; called by muse, mutect2, varscan2
- ERC1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV61699544; called by muse, mutect2, varscan2
- ERC2 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs866470365, COSV55609221, COSV55611425; called by muse, mutect2, varscan2
- ERCC6 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1344070217, COSV63393771; called by muse, mutect2, varscan2
- ERICH1 | c.494T>A p.L165Q | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50640939; called by muse, mutect2, varscan2
- ERICH3 | c.1307_1308dup p.Y437Sfs*3 | Frame Shift Ins (INS) | VAF 42/142 reads (30%) | catalogued as rs1179725780; called by mutect2, varscan2
- ERICH5 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs773195953, COSV59315251; called by muse, mutect2, varscan2
- ERV3-1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.283); catalogued as rs199709958; called by muse, mutect2, varscan2
- ESPNL | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58038214; called by muse, mutect2, varscan2
- ETF1 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs753167770, COSV100859990, COSV62128147; called by muse, mutect2, varscan2
- ETNPPL | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV56596920; called by muse, mutect2, varscan2
- EVPL | c.1699C>T p.H567Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs761710925, COSV56916086; called by muse, mutect2, varscan2
- EVPL | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV56916092; called by muse, varscan2
- EXOC6 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.492); catalogued as COSV53332603; called by muse, mutect2, varscan2
- EYS | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV61000041; called by muse, mutect2, varscan2
- EZH2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs747028969, COSV57460236; called by muse, varscan2
- F13A1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as rs538605561, CD116683, COSV53561508; called by muse, mutect2, varscan2
- FAM135A | c.3422G>A p.G1141D (on ENST00000370479 / NM_001351599.1; = p.G928D on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.355); catalogued as COSV52059136; called by muse, mutect2, varscan2
- FAM135B | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.038); catalogued as COSV52753322; called by muse, mutect2, varscan2
- FAM135B | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1225278509, COSV52753341; called by muse, mutect2, varscan2
- FAM135B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52725538, COSV52758416; called by muse, mutect2, varscan2
- FAM135B | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752489635, COSV50521991, COSV50523965; called by muse, mutect2, varscan2
- FAM160B1 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV65089697; called by muse, mutect2, varscan2
- FAM161B | c.892G>A p.E298K (on ENST00000651776; = p.E235K on NM_152445.3) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV54104308; called by muse, mutect2, varscan2
- FAM170A | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV58926190, COSV58927228; called by muse, mutect2, varscan2
- FAM227B | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV54819430; called by muse, mutect2, varscan2
- FAM234B | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as rs1256187615, COSV52197531; called by muse, mutect2, varscan2
- FAM47C | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.687); catalogued as rs375607348, COSV63728240; called by muse, mutect2, varscan2
- FAM71B | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV57231265; called by muse, mutect2, varscan2
- FAM83F | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1395053763, COSV61001553; called by muse, mutect2, varscan2
- FAM83H | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1554624021, COSV66353877, COSV66354673; called by muse, mutect2, varscan2
- FAM98C | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs1457248112, COSV99385165; called by muse, mutect2, varscan2
- FAT2 | c.9965C>T p.P3322L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1279326327, COSV55829277; called by muse, mutect2
- FAT3 | c.7777G>A p.E2593K | Missense Mutation (SNP) | VAF 257/435 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV53173440; called by muse, mutect2, varscan2
- FAT4 | c.13282C>T p.P4428S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs771543271, COSV58708583; called by muse, mutect2, varscan2
- FBN1 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.589); catalogued as COSV57325493, COSV57332075; called by muse, mutect2, varscan2
- FBN2 | c.4349T>C p.V1450A | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV52544927; called by muse, mutect2, varscan2
- FBXL16 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs996091910, COSV60965527; called by muse, mutect2, varscan2
- FBXL18 | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV66668633; called by muse, mutect2, varscan2
- FBXL4 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV57750002; called by muse, mutect2, varscan2
- FBXL5 | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as rs769570035, COSV58013832; called by muse, mutect2, varscan2
- FBXO10 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1017867269, COSV52835610; called by muse, mutect2, varscan2
- FBXO44 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | catalogued as COSV52355571; called by muse, mutect2, varscan2
- FCRL1 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV63826590; called by muse, mutect2, varscan2
- FCRL6 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58942687; called by muse, mutect2, varscan2
- FERD3L | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs766581757, COSV51761566; called by muse, mutect2, varscan2
- FFAR4 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370316092; called by muse, mutect2, varscan2
- FGF23 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs774018822, COSV52977989; called by muse, mutect2, varscan2
- FGF3 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61926911; called by muse, varscan2
- FGF5 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs202119277, COSV56891927; called by muse, mutect2, varscan2
- FGFBP1 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV52587303; called by muse, mutect2, varscan2
- FGG | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771885312, COSV60196857; called by mutect2, varscan2
- FIGN | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.592); catalogued as COSV60771803; called by muse, mutect2, varscan2
- FLG | c.12167G>A p.R4056K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs1469172095, COSV64249205; called by muse, mutect2, varscan2
- FLG | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 39/106 reads (37%) | catalogued as COSV64249211, COSV64249383; called by muse, mutect2, varscan2
- FLNC | c.1711G>A p.V571M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1194021325, COSV57964951; called by muse, mutect2, varscan2
- FMN2 | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV60453418; called by muse, mutect2, varscan2
- FMO3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868604370, COSV63007410; called by muse, varscan2
- FMO4 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs145740321; called by muse, mutect2, varscan2
- FNDC1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1364001630, COSV51936655, COSV51939017; called by muse, mutect2, varscan2
- FOLR1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs1370692247, COSV56617182; called by muse, mutect2, varscan2
- FOXD4L1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52076607; called by muse, mutect2, varscan2
- FOXI1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as rs779571186, COSV60388420; called by muse, mutect2
- FOXI1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs906548347, COSV60390060; called by muse, mutect2, varscan2
- FOXR2 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100189468, COSV59258974, COSV59259767; called by muse, mutect2, varscan2
- FRAS1 | c.5671C>T p.R1891C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs373573150; called by muse, mutect2, varscan2
- FREM2 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs201063766, COSV54844085; called by muse, mutect2, varscan2
- FREM2 | c.8861A>C p.D2954A | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54852306; called by muse, mutect2, varscan2
- FRMD4A | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); catalogued as COSV62269211; called by muse, varscan2
- FRMD7 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs780995406, CM074184, COSV53748855; called by muse, mutect2, varscan2
- FRMD8 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV58214207; called by muse, mutect2, varscan2
- FRMPD2 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.147); catalogued as COSV59723789; called by muse, mutect2, varscan2
- FRY | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV66580144; called by muse, mutect2, varscan2
- FSCB | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV61217478, COSV61219494; called by muse, mutect2, varscan2
- FSHR | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV58630795, COSV58634960; called by muse, mutect2, varscan2
- FUT9 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56156635; called by muse, mutect2, varscan2
- G6PC | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53832626; called by muse, mutect2, varscan2
- GABBR1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV63544527; called by muse, mutect2, varscan2
- GABBR2 | c.2579A>T p.Q860L | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.838); catalogued as COSV52319469; called by muse, mutect2, varscan2
- GABRB1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.094); catalogued as COSV54981483, COSV99782313; called by muse, mutect2, varscan2
- GABRG1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs940269899, COSV54951321; called by muse, mutect2, varscan2
- GABRP | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.42); catalogued as COSV54664661; called by muse, mutect2, varscan2
- GAK | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201472926; called by muse, mutect2, varscan2
- GALNT14 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs138204092, COSV61111155; called by muse, mutect2, varscan2
- GALNT7 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357099857, COSV53934482; called by muse, mutect2, varscan2
- GALNTL5 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV67181174; called by muse, mutect2, varscan2
- GANC | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | PolyPhen benign (0.009); catalogued as COSV100531229, COSV58811823; called by muse, mutect2, varscan2
- GBF1 | c.2192C>T p.P731L (on ENST00000369983 / NM_001377137.1; = p.P730L on NM_004193.3) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100890436, COSV64149011; called by muse, mutect2, varscan2
- GCM2 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866335625, COSV65276563; called by muse, mutect2, varscan2
- GDF10 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782143666; called by muse, varscan2
- GDF5 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV65499198; called by muse, mutect2, varscan2
- GEMIN5 | c.3224C>T p.A1075V | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53564866; called by muse, mutect2, varscan2
- GGT5 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs749024136, COSV54072477; called by muse, varscan2
- GGT5 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV54073671; called by muse, varscan2
- GGT7 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100322228; called by muse, mutect2, varscan2
- GIMAP1 | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56189786; called by mutect2, varscan2
- GIMAP2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.347); catalogued as COSV56235453; called by muse, mutect2, varscan2
- GIMAP2 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV56236353; called by muse, mutect2, varscan2
- GIMAP4 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV55434637; called by muse, mutect2, varscan2
- GIMAP8 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56233878; called by muse, mutect2, varscan2
- GJA10 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs560104434, COSV65355254; called by muse, mutect2, varscan2
- GJA8 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs782576252, COSV99569731; called by muse, mutect2
- GK2 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62627295; called by muse, mutect2, varscan2
- GK2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100726015, COSV62626400, COSV62628410; called by muse, mutect2, varscan2
- GLI2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs143139718; called by muse, mutect2, varscan2
- GLI3 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV67894910; called by muse, mutect2, varscan2
- GLRB | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100030180; called by muse, mutect2, varscan2
- GMDS | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs868623141, COSV66431278; called by muse, mutect2
- GOLGA1 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 69/117 reads (59%) | catalogued as COSV63024265; called by muse, mutect2, varscan2
- GORAB | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347780020, COSV63026909; called by muse, mutect2, varscan2
- GPATCH1 | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99404358; called by muse, mutect2, varscan2
- GPC5 | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV65629617; called by muse, mutect2, varscan2
- GPR174 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52134095; called by muse, mutect2, varscan2
- GPR179 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as rs1424064071; called by muse, varscan2
- GPR6 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs765386622, COSV51573631; called by muse, mutect2, varscan2
- GPR75 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61832329; called by muse, mutect2, varscan2
- GPRC6A | c.490A>G p.M164V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59955957; called by muse, mutect2, varscan2
- GPX6 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs758610701, COSV62659034; called by muse, varscan2
- GRAP | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs143281137, COSV99408275; called by muse, varscan2
- GRIA1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53624099, COSV53624371; called by muse, mutect2, varscan2
- GRIA1 | c.2679G>A p.M893I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.005); catalogued as rs1401088967, COSV53621449; called by muse, mutect2, varscan2
- GRIA2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52402787; called by muse, mutect2, varscan2
- GRIA3 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.968); catalogued as COSV99991864; called by muse, mutect2, varscan2
- GRIA3 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99991867; called by muse, mutect2, varscan2
- GRID2 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV56265868; called by muse, mutect2, varscan2
- GRID2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV56174151, COSV56263047; called by muse, mutect2, varscan2
- GRIN1 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV59300755, COSV99043314; called by muse, mutect2, varscan2
- GRIN2A | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58021069; called by muse, mutect2, varscan2
- GRIN2A | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs867335598, COSV58021524; called by muse, varscan2
- GRIN2A | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58043093; called by muse, mutect2, varscan2
- GRIN2A | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58056867; called by muse, mutect2, varscan2
- GRIN3A | c.2090G>A p.W697* | Nonsense Mutation (SNP) | VAF 64/109 reads (59%) | catalogued as COSV62458184; called by muse, mutect2, varscan2
- GRK2 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57754710; called by muse, varscan2
- GRK2 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as COSV57754717; called by muse, varscan2
- GRM1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV51142679; called by muse, mutect2, varscan2
- GRM3 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64479673; called by muse, mutect2, varscan2
- GRM6 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV51435546; called by muse, mutect2, varscan2
- GRM7 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756834019, COSV63171012; called by muse, mutect2, varscan2
- GRPEL2 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV61388215; called by muse, mutect2, varscan2
- GRXCR1 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.658); catalogued as COSV67674746; called by muse, mutect2, varscan2
- GTF3C1 | c.3923C>T p.S1308F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62242395; called by muse, mutect2, varscan2
- GUCY1A1 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.143); catalogued as COSV56656474; called by muse, mutect2, varscan2
- GUCY1A1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56656479; called by muse, mutect2, varscan2
- GUCY2C | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV53795543; called by muse, mutect2, varscan2
- GUCY2D | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV54698988; called by muse, mutect2, varscan2
- GXYLT1 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV55142625; called by muse, mutect2, varscan2
- GXYLT2 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159637462, COSV67475191; called by muse, mutect2, varscan2
- GYS2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53928885; called by muse, mutect2, varscan2
- GZMA | c.633T>G p.D211E | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57057455; called by muse, mutect2, varscan2
- H2BC21 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV58613194; called by muse, mutect2, varscan2
- HBE1 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV53081360; called by muse, mutect2, varscan2
- HDAC3 | c.302T>C p.F101S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59497860; called by muse, mutect2, varscan2
- HDAC4 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.946); catalogued as rs1175330507, COSV61874300; called by muse, mutect2, varscan2
- HDAC9 | c.1361T>G p.L454W | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67785184; called by muse, mutect2, varscan2
- HECTD4 | c.10447G>A p.A3483T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.93); catalogued as rs1207875442, COSV66393311, COSV66399847; called by muse, mutect2, varscan2
- HECW1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs889318847, COSV67830142; called by muse, mutect2, varscan2
- HECW1 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs752606904, COSV67839902; called by muse, mutect2, varscan2
- HELZ2 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64410481; called by muse, mutect2
- HEPACAM2 | c.587C>T p.S196F (on ENST00000394468 / NM_001039372.4; = p.S184F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); catalogued as COSV59063373; called by muse, mutect2, varscan2
- HERC1 | c.14341C>T p.R4781* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV71250255; called by muse, mutect2, varscan2
- HEXB | c.1152A>T p.E384D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV54670009; called by muse, mutect2, varscan2
- HFM1 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54022248; called by muse, mutect2, varscan2
- HGF | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV55948663, COSV55956826; called by muse, mutect2, varscan2
- HHAT | c.1159T>C p.C387R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.801); catalogued as COSV54809716; called by muse, mutect2, varscan2
- HHIP | c.10A>C p.M4L | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV56844121; called by muse, mutect2, varscan2
- HIP1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782070348, COSV61191492; called by muse, mutect2, varscan2
- HIVEP2 | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV50061988; called by muse, mutect2, varscan2
- HIVEP3 | c.3902C>T p.S1301L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV56023538; called by muse, mutect2, varscan2
- HIVEP3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs1397638118, COSV56023549; called by muse, mutect2, varscan2
- HLA-A | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs748125294, COSV65145667; called by muse, mutect2, varscan2
- HMCN1 | c.3775C>T p.Q1259* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV54941380; called by muse, mutect2, varscan2
- HMCN1 | c.8507C>T p.P2836L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54941396, COSV99625241; called by muse, mutect2, varscan2
- HMGB4 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53962732, COSV99594508; called by muse, mutect2, varscan2
- HMGCS2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 246/695 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65567281; called by muse, mutect2, varscan2
- HNRNPL | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs957250658, COSV55495421; called by muse, mutect2, varscan2
- HOOK3 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV56887805; called by muse, mutect2, varscan2
- HOXA2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs777207853, COSV56067774; called by muse, mutect2, varscan2
- HOXB1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs200228944, COSV53316987; called by muse, mutect2, varscan2
- HOXD10 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV50895478; called by muse, mutect2, varscan2
- HPSE2 | c.1450T>C p.C484R | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65201721; called by muse, varscan2
- HPX | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV56420636; called by muse, mutect2
- HR | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV57194711; called by muse, mutect2, varscan2
- HRNR | c.8548C>T p.Q2850* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV64258940; called by muse, mutect2, varscan2
- HRNR | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.068); catalogued as rs767260755, COSV64256124; called by muse, mutect2, varscan2
- HS6ST3 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as rs368419692; called by muse, mutect2, varscan2
- HSPA1L | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 202/584 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65149492; called by muse, mutect2, varscan2
- HSPA6 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as COSV59062622; called by muse, mutect2, varscan2
- HTN3 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV66879834; called by muse, mutect2, varscan2
- HTR1F | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1466882394, COSV60391217; called by muse, mutect2, varscan2
- HTR2C | c.389G>A p.W130* | Nonsense Mutation (SNP) | VAF 56/83 reads (67%) | catalogued as COSV52224663; called by muse, mutect2, varscan2
- HTR3B | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs867017410, COSV99492322; called by muse, mutect2, varscan2
- HTR3B | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV99492327; called by muse, mutect2, varscan2
- HTR4 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58804660; called by muse, mutect2, varscan2
- HYDIN | c.13144C>T p.P4382S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66642362; called by muse, mutect2, varscan2
- HYDIN | c.10639G>A p.E3547K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.442); catalogued as COSV66858470; called by muse, mutect2, varscan2
- HYDIN | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs201494207; called by muse, mutect2, varscan2
- HYDIN | c.6310G>A p.E2104K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV59270152; called by muse, mutect2, varscan2
- ICAM5 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs770648638, COSV55749289; called by muse, mutect2, varscan2
- IFIT1 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV65661521, COSV65661760; called by muse, mutect2, varscan2
- IGFN1 | c.3392C>T p.P1131L (on ENST00000295591 / NM_001367841.1; = p.P3588L on NM_001164586.2) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55184786; called by muse, mutect2, varscan2
- IGHD | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs373837383; called by muse, mutect2, varscan2
- IGHG3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT tolerated (0.31); catalogued as rs773477177; called by muse, varscan2
- IGKJ5 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as rs746860352; called by muse, mutect2, varscan2
- IGKV1D-43 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs1200199111; called by muse, mutect2, varscan2
- IGLV4-60 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs560499217, COSV66503763; called by muse, mutect2
- IGSF9 | c.3328C>T p.R1110W (on ENST00000368094 / NM_001135050.2; = p.R1094W on NM_020789.4) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.727); catalogued as rs775565374, COSV100230918; called by muse, mutect2, varscan2
- IHH | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV55392751; called by muse, mutect2, varscan2
- IL16 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs200499151, COSV57265480; called by muse, mutect2, varscan2
- IL17RC | c.824C>T p.P275L (on ENST00000295981 / NM_153461.4; = p.P204L on NM_153460.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs369736579, COSV99924879; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV56300657; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV100782078; called by muse, mutect2, varscan2
- IL1RL2 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV51818906; called by muse, mutect2, varscan2
- IL21R | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV61972617; called by muse, mutect2, varscan2
- IMPG1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs774782339, COSV64061849; called by muse, mutect2, varscan2
- IMPG1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1293334892, COSV64058034; called by muse, mutect2, varscan2
- INAVA | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1280074233, COSV66257546; called by muse, varscan2
- INHBA | c.388+2T>C p.X130_splice | Splice Site (SNP) | VAF 54/151 reads (36%) | catalogued as COSV99638441; called by muse, mutect2
- INHBC | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs768130925, COSV59006206; called by muse, mutect2, varscan2
- INPP1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as rs1201675308, COSV59417503; called by muse, mutect2, varscan2
- INPP5D | c.2398C>T p.Q800* (on ENST00000445964 / NM_001017915.3; = p.Q799* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV64040398; called by muse, mutect2, varscan2
- INTS6L | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV66086339; called by muse, mutect2, varscan2
- IPCEF1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54540833; called by muse, mutect2, varscan2
- IPO5 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55159829; called by muse, mutect2, varscan2
- IPO9 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as COSV64236144; called by muse, mutect2, varscan2
- IRAK2 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV56535798; called by muse, mutect2, varscan2
- IRX1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs868174444, COSV100116336, COSV57362387; called by muse, mutect2, varscan2
- IRX6 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV51862262; called by muse, mutect2, varscan2
- ISX | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV58088350; called by muse, mutect2, varscan2
- ITGA1 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV50898445; called by muse, mutect2, varscan2
- ITGA4 | c.554A>C p.Q185P | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV52003978; called by muse, mutect2
- ITGA4 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV52004207; called by muse, mutect2
- ITGAD | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV66760199; called by muse, mutect2, varscan2
- ITGAL | c.2508G>A p.K836= | Splice Region (SNP) | VAF 29/110 reads (26%) | catalogued as COSV63324365; called by muse, mutect2, varscan2
- ITGB8 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.235); catalogued as rs751381514, COSV56005590, COSV56015637; called by muse, mutect2, varscan2
- ITK | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV70065159; called by muse, mutect2, varscan2
- ITK | c.141G>A p.K47= | Splice Region (SNP) | VAF 74/192 reads (39%) | catalogued as COSV70065164; called by muse, varscan2
- ITK | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 92/194 reads (47%) | catalogued as COSV70065167; called by muse, varscan2
- ITK | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV70065170; called by muse, mutect2, varscan2
- JCAD | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs780210399, COSV64761657; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV59828434; called by muse, mutect2, varscan2
- KALRN | c.4541C>T p.S1514F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53780284; called by muse, mutect2, varscan2
- KANK2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV62009667; called by muse, mutect2, varscan2
- KANK4 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV62989347; called by mutect2, varscan2
- KCNB2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV73050743; called by mutect2, varscan2
- KCNH1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55083227, COSV55103701; called by muse, mutect2, varscan2
- KCNH5 | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100525445, COSV59777864; called by muse, mutect2, varscan2
- KCNH5 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59777872; called by muse, mutect2, varscan2
- KCNH7 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs867811019, COSV59813621; called by muse, mutect2, varscan2
- KCNJ16 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52255799; called by muse, mutect2, varscan2
- KCNK13 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs975551059, COSV56417755; called by muse, mutect2, varscan2
- KCNK18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV57973296; called by muse, mutect2, varscan2
- KCNK2 | c.1193C>T p.P398L (on ENST00000444842 / NM_001017425.3; = p.P383L on NM_014217.4) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101222270, COSV67206035; called by muse, mutect2, varscan2
2,058 further variants in this file (1,074 protein-altering or splice-affecting, 911 silent, 73 other) are not listed here.
